Somatic mutation profile of tumor specimen MMRF_1188_1_BM_CD138pos (aliquot MMRF_1188_1_BM_CD138pos_T1_KAS5U_L01216) from MMRF case MMRF_1188, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.3 years (27,869 days).
Specimen MMRF_1188_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8c92c02-eebc-4ba4-9a50-470e6c09b840.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1188_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1188_1_PB_Whole_C2_KAS5U_L01227; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5ea35b1-b659-4614-b43f-be5a4cedf45d

The open-access MAF lists 148 somatic variants for this specimen: 63 protein-altering or splice-affecting, 12 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, 3'UTR 42, Silent 12, Intron 12, RNA 6, 5'UTR 5, 3'Flank 5, Splice Site 4, 5'Flank 3, Translation Start Site 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 27/91 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 9/146 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AOC2 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV99513564; called by muse, mutect2, varscan2
- CDH23 | c.6454G>A p.V2152I | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs369493909, COSV56480716, COSV99818156; called by muse, mutect2, varscan2
- CFH | c.3497C>T p.P1166L | Missense Mutation (SNP) | VAF 95/104 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as CM131605; called by muse, mutect2, varscan2
- COL11A1 | c.1786G>T p.A596S | Missense Mutation (SNP) | VAF 70/83 reads (84%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100615218, COSV62174846; called by muse, varscan2
- DSE | c.140A>T p.Y47F | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100528868; called by muse, mutect2, varscan2
- FAM217A | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as rs1341844494; called by muse, mutect2, varscan2
- HMCN1 | c.2790+1G>A p.X930_splice | Splice Site (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99632772; called by muse, mutect2, varscan2
- IGHV1-69 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs370024749; called by muse, varscan2
- IGHV2-70D | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1310540287; called by muse, varscan2
- IGKJ5 | c.3G>C p.*1= | Missense Mutation (SNP) | VAF 36/124 reads (29%) | catalogued as rs368660113; called by muse, mutect2
- IGLV4-60 | c.329A>C p.D110A | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs368531437; called by muse, mutect2, varscan2
- ITK | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV70060465; called by muse, mutect2
- LAMA1 | c.7483G>A p.G2495S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758862251, COSV67544578; called by muse, mutect2, varscan2
- NEDD9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV65158864; called by muse, mutect2, varscan2
- NUP155 | c.3061G>A p.E1021K (on ENST00000231498 / NM_153485.3; = p.E962K on NM_004298.4) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV51534273, COSV51535046; called by muse, mutect2, varscan2
- PGLYRP2 | c.1287G>A p.M429I | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52993725; called by muse, mutect2
- PKHD1 | c.4889G>T p.G1630V | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61894895; called by muse, mutect2, varscan2
- RIMS2 | c.1963G>A p.E655K (on ENST00000666250 / NM_001348490.2; = p.E463K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.054); catalogued as rs772472518; called by muse, mutect2, varscan2
- SH3RF3 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs565113287; called by muse, mutect2, varscan2
- TLE2 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1489276289; called by muse, mutect2, varscan2
- ZCCHC7 | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762990163; called by muse, mutect2, varscan2
- ZNF101 | c.499A>G p.R167G | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770287277; called by muse, mutect2, varscan2
- AL031777.2 | c.388T>C p.F130L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANGPT1 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4901A>G p.E1634G | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2
- ATRX | c.3521C>G p.S1174C | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- BICRA | c.3785C>T p.A1262V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, varscan2
- BMPR1B | c.384A>T p.L128F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BTG1 | c.148+1G>A p.X50_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | called by mutect2, varscan2
- C16orf78 | c.523A>G p.R175G | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CCDC43 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CDK13 | c.436T>A p.Y146N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CDON | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRM1 | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DERL3 | c.548A>C p.Y183S | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH12 | c.3763G>A p.A1255T (on ENST00000351747; = p.A1278T on NM_001366028.2) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EGR1 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by mutect2, varscan2
- IGHV2-70D | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.189); called by muse, varscan2
- KDM1B | c.2243C>T p.P748L (on ENST00000449850; = p.P515L on NM_153042.4) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM4F | c.319del p.Y107Ifs*45 | Frame Shift Del (DEL) | VAF 16/123 reads (13%) | called by mutect2, pindel, varscan2
- KLF3 | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LAMB1 | c.3268C>T p.H1090Y | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.236); called by muse, mutect2
- LHCGR | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MME | c.2105A>T p.Y702F | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NAALADL2 | c.2134C>A p.L712I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- NLRP5 | c.3493G>A p.V1165M | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- NUP205 | c.3577C>T p.Q1193* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- PKIB | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.046); called by mutect2, varscan2
- PLD1 | c.1742A>T p.D581V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.432); called by muse, mutect2
- PNLIPRP3 | c.809-1G>A p.X270_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- PTPN6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RAG1 | c.2681C>G p.P894R | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RELB | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SHANK1 | c.5870G>A p.G1957E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- SLIT3 | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SPRY2 | c.361A>C p.S121R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SPRY2 | c.360C>G p.S120R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- TCEAL4 | c.63+2T>C p.X21_splice | Splice Site (SNP) | VAF 23/26 reads (88%) | called by muse, mutect2, varscan2
- TTN | c.26442dup p.E8815Rfs*28 (on ENST00000591111; = p.E7888Rfs*28 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 71/111 reads (64%) | called by mutect2, pindel, varscan2
- VENTX | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF233 | c.1752A>T p.R584S | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.234); called by muse, mutect2
- ATRN | c.2085C>T p.S695= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV53533979; called by muse, mutect2
- COL20A1 | c.849G>A p.V283= | Silent (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- CTNND1 | c.558C>A p.G186= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV62385007; called by muse, mutect2
- DYSF | c.2139G>A p.T713= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs754423332, COSV50370004; called by muse, mutect2
- EPM2A | c.711C>T p.S237= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- FAT3 | c.6612C>A p.P2204= | Silent (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- FBXW5 | c.1293C>T p.A431= | Silent (SNP) | VAF 66/145 reads (46%) | catalogued as rs372957829; called by muse, mutect2, varscan2
- IGHV1-69 | c.246G>A p.K82= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as rs375048404; called by muse, varscan2
- NPY4R | c.228C>T p.T76= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs146477439; called by muse, mutect2, varscan2
- PKHD1 | c.8133C>T p.V2711= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as COSV100580717; called by muse, mutect2, varscan2
- RIMS1 | c.624G>A p.K208= | Silent (SNP) | VAF 7/121 reads (6%) | catalogued as COSV99330089; called by muse, mutect2
- SEZ6L2 | c.2035C>T p.L679= (on ENST00000308713 / NM_001114099.3; = p.L609= on NM_012410.4) | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs373907385; called by muse, mutect2, varscan2
- ABCC5 | c.591+884A>G | Intron (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+9232C>T | Intron (SNP) | VAF 28/36 reads (78%) | catalogued as rs779997366; called by muse, mutect2, varscan2
- ACVR2B | c.-40C>T | 5'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- ADGRL3 | chr4:62071792 A>C | 3'Flank (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- AP000281.2 | chr21:32852487 A>G | 5'Flank (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021466 C>T | 5'Flank (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- BMP6 | c.*587G>A | 3'UTR (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- C19orf25 | c.131-363G>A | Intron (SNP) | VAF 10/13 reads (77%) | catalogued as rs1478892447; called by muse, mutect2, varscan2
- C1orf21 | c.*4585C>G | 3'UTR (SNP) | VAF 70/82 reads (85%) | called by muse, mutect2, varscan2
- CACNG4 | c.*424C>T | 3'UTR (SNP) | VAF 15/41 reads (37%) | catalogued as rs958985404, COSV100048060; called by muse, mutect2, varscan2
- CDH7 | chr18:65882832 G>A | 3'Flank (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- CEP85L | c.*2268A>C | 3'UTR (SNP) | VAF 40/97 reads (41%) | catalogued as rs947920378; called by muse, mutect2, varscan2
- COBL | c.1096+12866T>A | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*2690G>T | 3'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- CYP2A7P1 | n.360C>T | RNA (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- DCC | c.*5121T>C | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- DEFB127 | c.*70C>A | 3'UTR (SNP) | VAF 40/103 reads (39%) | catalogued as COSV101213901; called by muse, mutect2
- DUSP4 | c.*1272C>T | 3'UTR (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- ELL2 | c.*1334C>G | 3'UTR (SNP) | VAF 15/89 reads (17%) | catalogued as rs1005050473; called by muse, mutect2, varscan2
- FAHD2A | c.*3033G>A | 3'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- FOSL2 | c.*2880G>A | 3'UTR (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- GLUD2 | c.-10G>A | 5'UTR (SNP) | VAF 11/37 reads (30%) | catalogued as rs772903729; called by muse, mutect2, varscan2
- H2BC21 | c.*58G>A | 3'UTR (SNP) | VAF 43/51 reads (84%) | called by muse, mutect2, varscan2
- HDAC2 | c.*531C>T | 3'UTR (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- IGHA1 | c.*32T>C | 3'UTR (SNP) | VAF 12/34 reads (35%) | catalogued as rs1196988603; called by muse, mutect2
- IGHV1-69D | c.-3A>T | 5'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- IGLC3 | c.*21A>C | 3'UTR (SNP) | VAF 23/71 reads (32%) | catalogued as rs200606818; called by muse, mutect2, varscan2
- IL22 | chr12:68248706 T>A | 3'Flank (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- KCNU1 | c.-19G>A | 5'UTR (SNP) | VAF 25/80 reads (31%) | catalogued as rs373161433; called by muse, mutect2, varscan2
- LCP2 | c.*1965G>C | 3'UTR (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- LILRA2 | c.1255+1431G>T | Intron (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- MIR5195 | n.3G>A | RNA (SNP) | VAF 43/75 reads (57%) | catalogued as rs535424470; called by muse, mutect2, varscan2
- NUDT16 | c.*379G>T | 3'UTR (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- OAT | c.*278G>A | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- OLFML1 | c.*770C>T | 3'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- PABPC1P2 | n.660C>T | RNA (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+3279C>T | Intron (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- PCYT1B | c.*2036T>C | 3'UTR (SNP) | VAF 45/55 reads (82%) | called by muse, mutect2, varscan2
- PIEZO2 | chr18:10670312 G>C | 3'Flank (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- PRMT8 | c.*287G>A | 3'UTR (SNP) | VAF 38/91 reads (42%) | catalogued as rs574967859; called by muse, mutect2, varscan2
- PTPRH | c.85+14G>T | Intron (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- RNF128 | c.*123A>C | 3'UTR (SNP) | VAF 12/12 reads (100%) | called by muse, varscan2
- RNF8 | c.*1753_*1754del | 3'UTR (DEL) | VAF 34/85 reads (40%) | called by pindel, varscan2
- RORA | c.*8157C>T | 3'UTR (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- RPL23 | c.*15+775A>G | Intron (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+722C>G | Intron (SNP) | VAF 39/99 reads (39%) | catalogued as COSV73912781; called by muse, mutect2, varscan2
- SARDH | c.*217A>G | 3'UTR (SNP) | VAF 5/77 reads (6%) | catalogued as rs956809566, COSV64099881; called by muse, mutect2
- SCD5 | c.*961G>A | 3'UTR (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- SEC1P | n.396C>T | RNA (SNP) | VAF 40/241 reads (17%) | called by muse, mutect2, varscan2
- SEMA5A | c.*3731T>C | 3'UTR (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- SLC19A2 | c.*569G>T | 3'UTR (SNP) | VAF 62/76 reads (82%) | catalogued as rs1480122840; called by muse, mutect2, varscan2
- SLC36A2 | c.1180+62C>T | Intron (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- SLC6A11 | c.*543G>C | 3'UTR (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-476C>T | 5'UTR (SNP) | VAF 32/50 reads (64%) | called by muse, mutect2, varscan2
- SMOC2 | c.*323C>T | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- SNORD115-25 | chr15:25218712 A>G | 3'Flank (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- STAT3 | c.*1867C>T | 3'UTR (SNP) | VAF 3/44 reads (7%) | catalogued as rs894889757, COSV99232727; called by muse, mutect2
- SUPT3H | c.*967dup | 3'UTR (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- SYT4 | c.*2319T>C | 3'UTR (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- SZRD1 | c.*2089C>T | 3'UTR (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- TCP1P1 | n.298T>G | RNA (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975590 C>G | 5'Flank (SNP) | VAF 47/55 reads (85%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- TSPAN11 | c.*4383T>G | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*777C>T | 3'UTR (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- UBFD1 | c.*792G>T | 3'UTR (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- UBL3 | c.*28T>C | 3'UTR (SNP) | VAF 20/130 reads (15%) | catalogued as rs367925955; called by muse, mutect2, varscan2
- UGGT2 | c.1031+1031C>T | Intron (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- VGLL3 | c.*5797T>A | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- VN1R6P | n.14A>T | RNA (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2
- VXN | c.*455A>G | 3'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- WNT7B | c.*1944C>T | 3'UTR (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- ZNF142 | c.*1219G>A | 3'UTR (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- ZNF415 | c.-194-122C>T | Intron (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
